Surgical pathology report (de-identified scan), TCGA case TCGA-34-2604, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-34-2604-01A (Primary Tumor).

[page 1 of 4]
carcinoma.

PRE OP DIAGNOSIS: Lung cancer.

POST OP DIAGNOSIS: Same.

PROCEDURE: Bronchoscopy, mediastinoscopy, left lower lobectomy.

FINAL DIAGNOSIS

Summary Statement

The left lower lobe neoplasm is a poorly differentiated invasive squamous cell carcinoma (5.0 x 5.0 x 4.0 cm) with extensive necrosis. The vascular, bronchial and parenchymal surgical resection margins are free of tumor. However, the tumor extends to the visceral pleural margin. The lymph nodes are negative for metastatic carcinoma. The stage is: T2N0MX.

PART 1: LYMPH NODE, RIGHT LEVEL 4, EXCISION

FRAGMENTS OF BENIGN REACTIVE LYMPH NODE WITH NO CARCINOMA SEEN.

PART 2: LYMPH NODE, LEFT LEVEL 4, EXCISION

FRAGMENTS OF BENIGN REACTIVE LYMPH NODE WITH NO CARCINOMA SEEN.

PART 3: PRETRACHEAL LYMPH NODE, LEVEL 3, EXCISION

FRAGMENTS OF BENIGN REACTIVE LYMPH NODE WITH NO CARCINOMA SEEN.

PART 4: LYMPH NODE, SUBCARINAL EXCISION

TWO (2) BENIGN REACTIVE LYMPH NODES WITH NO CARCINOMA SEEN.

PART 5: LYMPH NODE, 11, EXCISION

ONE (1) BENIGN REACTIVE LYMPH NODE WITH NO CARCINOMA SEEN.

PART 6: PLEURAL, CHEST WALL, EXCISION

PARIETAL PLEURA WITH MODERATE CHRONIC INFLAMMATION BUT NO CARCINOMA SEEN.

PART 7: LUNG, LEFT LOWER LOBE, LOBECTOMY

A. INVASIVE, POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA (5.0 x 5.0 x 4.0 CM) WITH EXTENSIVE NECROSIS.

B. TUMOR EXTENDING TO VISCERAL PLEURAL MARGIN.

C. BRONCHIAL AND VASCULAR RESECTION MARGINS FREE OF TUMOR.

D. SEVEN (7) PERIBRONCHIAL LYMPH NODES NEGATIVE FOR METASTATIC TUMOR.

E. BACKGROUND LUNG WITH EMPHYSEMATOUS CHANGES AND AIRSPACE ACCUMULATION OF SMOKER'S MACROPHAGES.

F. STAGE: T2, N0, MX.

PART 8: LYMPH NODE, SUMP NODE, EXCISION

BENIGN REACTIVE LYMPH NODE WITH NO CARCINOMA SEEN.

COMMENT

{Not Entered}

GROSS DESCRIPTION

[page 2 of 4]
The specimen is received fresh and in eight parts.

Part 1 labeled "right level 4 lymph node" consists of multiple portions of tan and anthracotic lymphoid tissue, 0.5 to 0.7 cm in greatest dimension, entirely submitted in sections "1A" through "1C".

Part 2 labeled "left level 4 lymph node" consists of three, irregular portions of tan and anthracotic lymphoid tissue, 0.3 to 0.8 cm in greatest dimension, entirely submitted labeled "2A".

Part 3 labeled "pretracheal level 3 lymph node" consists of multiple portions of tan and anthracotic lymphoid tissue, 0.3 to 0.5 cm in greatest dimension, entirely submitted following frozen section evaluation, labeled "3A".

Part 4 labeled "subcarinal lymph node" consists of three, irregular portions of anthracotic, soft, lymphoid tissue, 0.3 to 0.7 cm in greatest dimension, entirely submitted labeled "4A".

Part 5 labeled "number 11 lymph node" consists of a single, encapsulated, anthracotic node, 1.0 cm in greatest dimension, bisected and entirely submitted labeled "5A".

Part 6 labeled "chest wall pleura" consists of a 1.5 x 1.0 x 0.7 cm of pink to hemorrhagic, soft to rubbery tissue, entirely submitted following frozen section evaluation labeled "6A" and "6B".
uts

Part 7 is labeled "left lower lobe" and consists a 450 gram lung lobectomy, measuring 17.0 x 16.0 x 7.0 cm., with an irregular tan anthracotic pleural surface and a 5.0 x 5.0 x 4.0 cm. palpable mass umbilicating the pleura at the posterior/lateral aspect. On cross-section, the tumor is irregular, grey-white and soft, not grossly infiltrating bronchus. The surrounding uninvolved lung parenchyma is tan to anthracotic. No satellite lesions are seen. The hilar structures and lymph nodes are grossly free of tumor. Representative tissue is frozen in bulk. The following sections are submitted:

7A Bronchial resection margin following frozen section evaluation

7B Vascular resection margin

7C Hilar lymph node

7D and 7E Tumor with relation to pleural surface

7F and 7G Tumor and adjacent normal

7H and 7I Parenchymal resection margins with ink

Part 8 is labeled "sump node" and consists of a 1.2 x 1.0 x 0.4 cm. anthracotic lymph node which is entirely submitted labeled 8A.

P.7,8 ncs

MICROSCOPIC DESCRIPTION

SYNOPTIC PRIMARY LUNG TUMORS

A.Location: 4

1. RUL

3. RLL

5. LUL

2. RML

4. LLL

6. Bronchus intermedius

B.Procedure: 2

1.Wedge/Segmental

3. Bilobectomy

2.Lobectomy

4. Pneumonectomy

C.Size of tumor (maximum dimension): 5 cm.

D.Satellite nodules: 2

1. yes

2. no

E.Type: 1

1.Invasive squamous carcinoma

9. Sarcomatoid carcinoma

[page 3 of 4]
2. Basaloid squamous carcinoma
3. Invasive adenocarcinoma
4. Bronchioloalveolar carcinoma, nonmucinous type
5. Bronchioloalveolar carcinoma, mucinous type
6. Large cell carcinoma
7. Clear cell carcinoma
8. Giant cell carcinoma

F. Grade: 3

1. well
2. moderate

G. Bronchogenic (versus parenchymal) origin: 1

1. yes
2. no

H. Visceral pleural invasion: 1

1. yes
2. no

I. Parietal pleural invasion: 2

1. yes
2. no

J. Chest wall invasion: 2

1. yes
2. no

K. Angiolymphatic invasion: 2

1. yes
2. no

L. Surgical margins involved: 2

1. yes
2. no

M. Inflammatory (desmoplastic) reaction: 2

1. mild
2. moderate

N. Hilar lymph node involvement: 2

1. yes
2. no

O. If hilar lymph nodes involved.

P. Mediastinal nodes involved: 2

1. yes
2. no

Q. Mediastinal node group(s) involved:

- | | | | |
|-------------|--------------|-------------|---------------|
| 1. Level 4R | 4. Level 7R | 7. Level 4L | 10. Level 7L |
| 2. Level 5R | 5. Level 9R | 8. Level 5L | 11. Level 9L |
| 3. Level 6R | 6. Level 10R | 9. Level 6L | 12. Level 10L |

R. Underlying disease(s): 1

- | | | |
|-------------------|--------------------------|---------------------|
| 1. Emphysema | 3. Tumorlets | 5. Asthma |
| 2. Bronchiectasis | 4. Smokers bronchiolitis | 6. Parenchymal scar |

S. TNM Stage: T 2 N 0 M X

10. Blastoma
11. Fetal type adenocarcinoma
12. Oat cell carcinoma
13. Carcinoid
14. Atypical carcinoid
15. Sarcoma
16. Other

3. poor/undifferentiated

3. severe

3. not applicable

INTRAOPERATIVE DIAGNOSIS

PART 1: RIGHT LEVEL 4 LYMPH NODES, BIOPSY (frozen section)

A. BENIGN.

B. NO TUMOR SEEN [REDACTED]

PART 2: LEFT LEVEL 4 LYMPH NODE (frozen section)

A. BENIGN.

B. NO TUMOR SEEN.

PART 3: PRETRACHEAL LEVEL 3 NODE (frozen section) -

A. BENIGN.

B. NO TUMOR SEEN.

PART 4: SUBCARINAL LYMPH NODES (frozen section) -

A. BENIGN.

B. NO TUMOR SEEN [REDACTED]

PART 6: CHEST WALL PLEURA (frozen section) -

[page 4 of 4]
- A. BENIGN.
- B. NO TUMOR SEEN ([REDACTED])
- uts

PART 7: LEFT LOWER LUNG, BRONCHIAL MARGIN (Frozen section)

- A. BENIGN.
- B. NO TUMOR SEEN. [REDACTED]

Source: NCI Genomic Data Commons file 24436a48-20a1-44dc-8268-6c175c6a29f9 (TCGA-34-2604.8A9824BD-7B50-4AD8-BD84-DFA29A88D6B2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).